Gene-level copy-number profile of tumor specimen TCGA-CV-5978-01A from TCGA case TCGA-CV-5978, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 53.3 years (19,480 days).
Specimen TCGA-CV-5978-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.e854fedc-32cb-431e-ab66-fc27cda5f6cd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-5978-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1e7d0626-81d2-4fa9-8703-49d959e17780

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 883; copy number 2: 12,547; copy number 3: 30,589; copy number 4: 9,706; copy number 5: 5,016; copy number 6: 65; copy number 7: 352; copy number 9: 651; copy number 11: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-5978-01A-11D-1682-01): tumor purity 0.38, ploidy 3.08, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,007 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:140,941,830–198,222,513, 1,001 genes, copy number 7–9 (broad region; genes not listed).
- chr8:127,072,694–127,227,541, 1 gene, copy number 11 (within-gene range 5–11): CASC19.
- chr8:127,253,213–127,257,630, 1 gene, copy number 11: AC018714.2.
- chr8:127,292,233–127,420,066, 2 genes, copy number 11 (within-gene range 4–11): AC018714.1, POU5F1B.
- chr16:77,247,813–77,446,798, 2 genes, copy number 7 (within-gene range 4–7): ADAMTS18, AC025284.1.

Autosomal genes at a single copy (total copy number 1): 883. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
